Somatic mutation profile of tumor specimen TCGA-DD-A4ND-01A (aliquot TCGA-DD-A4ND-01A-11D-A25V-10) from TCGA case TCGA-DD-A4ND, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 56.9 years (20,782 days).
Specimen TCGA-DD-A4ND-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa3e6d88-b71a-4d1c-87b4-625625e64108.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4ND-11A (Solid Tissue Normal), aliquot TCGA-DD-A4ND-11A-11D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c3a1ad6-f3ce-409b-80c3-15061dd90366

The open-access MAF lists 64 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 14, Nonsense Mutation 4, 5'UTR 1, In Frame Del 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAT1 | c.632A>G p.Q211R | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54920753; called by muse, mutect2, varscan2
- ARHGAP6 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV57294838; called by muse, mutect2, varscan2
- CDK12 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.97); catalogued as rs775376309, COSV71000363; called by muse, mutect2, varscan2
- CELSR2 | c.1990G>A p.G664S | Missense Mutation (SNP) | VAF 59/289 reads (20%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.951); catalogued as COSV54770164; called by muse, mutect2, varscan2
- DCLK1 | c.1031A>C p.Q344P | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.162); catalogued as COSV55183029; called by muse, mutect2, varscan2
- DNHD1 | c.11848T>A p.S3950T | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV54434140; called by muse, mutect2, varscan2
- DSC2 | c.2167A>T p.K723* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as COSV51863861; called by muse, mutect2, varscan2
- FOXD2 | c.556G>C p.V186L | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV58303936; called by muse, mutect2, varscan2
- FOXRED2 | c.249G>C p.K83N | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53399641; called by muse, mutect2, varscan2
- GSTP1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 24/528 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752731774, COSV66992384; called by muse, mutect2
- KIAA0586 | c.4108T>G p.F1370V (on ENST00000619416 / NM_001244190.2; = p.F1309V on NM_014749.5) | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV54174523; called by muse, mutect2, varscan2
- KRT27 | c.817A>T p.R273W | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56971546; called by muse, varscan2
- LMO7 | c.1787G>A p.C596Y (on ENST00000357063; = p.C326Y on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58534440; called by muse, mutect2, varscan2
- LTN1 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.723); catalogued as COSV63733558; called by muse, mutect2, varscan2
- MAGI2 | c.1723G>T p.D575Y | Missense Mutation (SNP) | VAF 149/443 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62636788, COSV62648582; called by muse, mutect2, varscan2
- MAN2A2 | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776525016, COSV64637990; called by muse, mutect2, varscan2
- MINAR1 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV59582349; called by muse, mutect2, varscan2
- MYO1H | c.2545C>T p.Q849* | Nonsense Mutation (SNP) | VAF 36/248 reads (15%) | catalogued as COSV60444980; called by muse, mutect2, varscan2
- MYO6 | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1199128164, COSV64118393; called by muse, mutect2, varscan2
- NASP | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 53/314 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV63112729; called by muse, mutect2, varscan2
- NEB | c.7343G>A p.R2448H | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373589529, COSV51135223; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NIPSNAP2 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 61/173 reads (35%) | catalogued as COSV59050913; called by muse, mutect2, varscan2
- NPY5R | c.160C>A p.L54I | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV58451750; called by muse, mutect2, varscan2
- NUMB | c.1118T>G p.F373C (on ENST00000355058; = p.F362C on NM_003744.5) | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.371); catalogued as COSV61568575; called by muse, mutect2, varscan2
- OR6N2 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs200003269, COSV59411122; called by muse, mutect2, varscan2
- OR7A10 | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV50166252; called by muse, mutect2, varscan2
- OR7A5 | c.271G>T p.V91F | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV59234536; called by muse, mutect2
- OR8H1 | c.491G>A p.R164K | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV57293805, COSV57294512; called by muse, mutect2, varscan2
- P2RY4 | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 87/399 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65736446; called by muse, mutect2, varscan2
- PARP11 | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV57394648; called by muse, mutect2, varscan2
- PCDH10 | c.1612G>A p.D538N | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.382); catalogued as COSV52092296, COSV52092303, COSV52094318; called by muse, mutect2, varscan2
- RBM11 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 79/375 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV68748057; called by muse, mutect2, varscan2
- RGS12 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781197412, COSV60904086; called by muse, mutect2, varscan2
- RNF113A | c.275A>T p.E92V | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV65097277; called by muse, mutect2
- SACS | c.5494T>A p.F1832I | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.637); catalogued as COSV66538693; called by muse, mutect2
- SEMA4A | c.1960G>C p.A654P | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.451); catalogued as COSV61772549; called by muse, mutect2, varscan2
- SPRR2E | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.125); catalogued as COSV64203746; called by muse, mutect2, varscan2
- TENT4A | c.2242G>A p.G748S | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.014); catalogued as rs762098149, COSV50095340; called by muse, mutect2, varscan2
- TSPEAR | c.1667A>C p.N556T | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV59959358; called by muse, varscan2
- TTC28 | c.6768G>C p.E2256D | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV104431532, COSV67416201; called by muse, mutect2, varscan2
- UNC45B | c.964T>A p.Y322N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.366); catalogued as COSV52094665; called by muse, mutect2, varscan2
- USP6 | c.1424G>A p.W475* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as rs1376515778, COSV51475898; called by muse, mutect2, varscan2
- UTP15 | c.1136G>T p.R379I | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as COSV57146045; called by muse, mutect2, varscan2
- WAS | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as CD043710, COSV64996947; called by muse, mutect2, varscan2
- ZFHX3 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs200390317, COSV104391263, COSV51709558; called by muse, varscan2
- ZNF410 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs764006881, COSV57910495; called by muse, varscan2
- CHST13 | c.162_167del p.K54_Y56delinsN | In Frame Del (DEL) | VAF 19/148 reads (13%) | called by mutect2, pindel, varscan2
- TGS1 | c.599del p.K200Sfs*89 | Frame Shift Del (DEL) | VAF 34/97 reads (35%) | called by mutect2, pindel, varscan2
- ARHGAP25 | c.1263C>T p.D421= (on ENST00000409202 / NM_001007231.3; = p.D413= on NM_014882.3) | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV54901448; called by muse, mutect2
- CSAD | c.1233T>C p.N411= (on ENST00000444623 / NM_001244705.2; = p.N438= on NM_015989.5) | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as COSV57242283; called by muse, mutect2, varscan2
- DOP1B | c.3940C>T p.L1314= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV67693047; called by muse, mutect2, varscan2
- G6PC2 | c.33A>C p.I11= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV56371987; called by muse, mutect2, varscan2
- GLDC | c.2022G>T p.G674= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as COSV58679129; called by muse, mutect2, varscan2
- GPR171 | c.828G>T p.S276= | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as COSV56376311, COSV56387613; called by muse, mutect2, varscan2
- GSE1 | c.2511G>A p.Q837= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as rs763330643, COSV53671436, COSV53674666; called by muse, mutect2, varscan2
- LPIN2 | c.774A>G p.S258= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV55239175; called by muse, mutect2, varscan2
- LRRK2 | c.4719T>G p.V1573= | Silent (SNP) | VAF 42/175 reads (24%) | catalogued as COSV54150555; called by muse, mutect2, varscan2
- MAP7D3 | c.1971A>G p.Q657= | Silent (SNP) | VAF 41/259 reads (16%) | catalogued as COSV60170706; called by muse, mutect2, varscan2
- MROH2A | c.2380T>C p.L794= | Silent (SNP) | VAF 52/238 reads (22%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.2076C>T p.Y692= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV53905061, COSV53933071; called by muse, mutect2, varscan2
- RALGAPA2 | c.450G>T p.L150= | Silent (SNP) | VAF 43/269 reads (16%) | catalogued as COSV52495222; called by muse, mutect2, varscan2
- ZNF217 | c.1227C>G p.T409= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV56596300; called by muse, mutect2, varscan2
- ATF2 | c.-15T>C | 5'UTR (SNP) | VAF 38/164 reads (23%) | catalogued as COSV99908698; called by muse, mutect2, varscan2
- PURA | c.*2334_*2335del | 3'UTR (DEL) | VAF 18/121 reads (15%) | called by pindel, varscan2
